Somatic mutation profile of tumor specimen TCGA-D1-A16N-01A (aliquot TCGA-D1-A16N-01A-11D-A12J-09) from TCGA case TCGA-D1-A16N, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 51.4 years (18,787 days).
Specimen TCGA-D1-A16N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf56d819-3a8b-4057-91ff-44b00d8d07c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A16N-10A (Blood Derived Normal), aliquot TCGA-D1-A16N-10A-01D-A12J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae6dfa7e-625c-465e-ba30-edd59e885708

The open-access MAF lists 145 somatic variants for this specimen: 114 protein-altering or splice-affecting, 27 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 27, Frame Shift Del 14, Nonsense Mutation 9, Frame Shift Ins 4, Splice Site 3, RNA 2, In Frame Del 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1742del p.K581Rfs*9 | Frame Shift Del (DEL) | VAF 78/194 reads (40%) | catalogued as rs1060503259, CM1110730, COSV57340306; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.1258T>C p.C420R | Missense Mutation (SNP) | VAF 92/180 reads (51%) | hotspot (GDC flag); SIFT tolerated (0.21); PolyPhen possibly damaging (0.908); catalogued as rs121913272, COSV55874020; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.419T>G p.L140* | Nonsense Mutation (SNP) | VAF 139/188 reads (74%) | hotspot (GDC flag); catalogued as COSV64289095, COSV64298590; called by muse, mutect2, varscan2
- RB1 | c.1215+1G>A p.X405_splice | Splice Site (SNP) | VAF 65/84 reads (77%) | hotspot (GDC flag); catalogued as rs587776783, CS890133, CS982341, COSV57294684, COSV57294939, COSV57306748; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.716A>G p.N239S | Missense Mutation (SNP) | VAF 66/88 reads (75%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.772); catalogued as rs1057519999, COSV52661127, COSV52664176, COSV52966384; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AC005324.2 | c.884C>T p.T295I | Missense Mutation (SNP) | VAF 19/212 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.117); catalogued as COSV60885576; called by muse, mutect2
- ACACB | c.5842C>T p.R1948* | Nonsense Mutation (SNP) | VAF 39/154 reads (25%) | catalogued as rs554134867, COSV58127981; called by muse, mutect2, varscan2
- ADAMTS19 | c.2944T>C p.C982R | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50731889; called by muse, mutect2
- ADCY3 | c.1297G>A p.D433N | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs901136767, COSV53164234; called by muse, mutect2, varscan2
- AFP | c.1043del p.N348Ifs*22 | Frame Shift Del (DEL) | VAF 20/79 reads (25%) | catalogued as rs779815391; called by mutect2, pindel, varscan2
- ANKRD50 | c.2432A>T p.D811V | Missense Mutation (SNP) | VAF 95/204 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV72385022; called by muse, mutect2, varscan2
- ASIC1 | c.1282A>T p.I428F | Missense Mutation (SNP) | VAF 63/232 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV57316020; called by muse, mutect2, varscan2
- ATRNL1 | c.3091T>C p.C1031R | Missense Mutation (SNP) | VAF 85/164 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs782485662, COSV58073583; called by muse, mutect2, varscan2
- BRIP1 | c.2335G>A p.V779I | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV51993847; called by muse, mutect2, varscan2
- C16orf70 | c.911T>C p.V304A | Missense Mutation (SNP) | VAF 14/189 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.104); catalogued as COSV54625517; called by muse, mutect2
- C1QL2 | c.421G>C p.D141H | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.114); catalogued as COSV55605957, COSV55607624; called by muse, mutect2, varscan2
- CDKN2AIP | c.616G>T p.G206* | Nonsense Mutation (SNP) | VAF 35/136 reads (26%) | catalogued as COSV56626714; called by muse, mutect2, varscan2
- CHCHD7 | c.54+2T>C p.X18_splice (on ENST00000355315 / NM_001011671.3; = p.X30_splice on NM_024300.4) | Splice Site (SNP) | VAF 115/591 reads (19%) | catalogued as rs1257442475, COSV57609160; called by muse, mutect2, varscan2
- COL2A1 | c.2473G>C p.G825R | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM103265, COSV61527738; called by muse, mutect2, varscan2
- CSMD1 | c.4821T>G p.I1607M (on ENST00000520002; = p.I1606M on NM_033225.6) | Missense Mutation (SNP) | VAF 76/389 reads (20%) | SIFT tolerated (1); PolyPhen possibly damaging (0.639); catalogued as COSV59280586; called by muse, mutect2, varscan2
- CSMD3 | c.3142C>A p.L1048I (on ENST00000297405 / NM_001363185.1; = p.L944I on NM_052900.3) | Missense Mutation (SNP) | VAF 79/281 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.246); catalogued as rs1038971284, COSV52100311, COSV52199877, COSV52252257; called by muse, mutect2, varscan2
- CWC27 | c.1387A>C p.K463Q | Missense Mutation (SNP) | VAF 62/82 reads (76%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.991); catalogued as COSV66883934; called by muse, mutect2, varscan2
- CYB5R4 | c.741del p.E248Rfs*12 | Frame Shift Del (DEL) | VAF 49/284 reads (17%) | catalogued as rs745836350; called by mutect2, varscan2
- DENND4B | c.304dup p.L102Pfs*3 | Frame Shift Ins (INS) | VAF 16/66 reads (24%) | catalogued as rs747842790; called by mutect2, varscan2
- DOCK2 | c.2438A>C p.K813T | Missense Mutation (SNP) | VAF 31/414 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.398); catalogued as COSV56941136; called by muse, mutect2
- DRG2 | c.611A>G p.Q204R | Missense Mutation (SNP) | VAF 59/115 reads (51%) | SIFT tolerated (0.69); PolyPhen benign (0.006); catalogued as COSV56727651; called by muse, mutect2, varscan2
- DROSHA | c.1910C>G p.P637R | Missense Mutation (SNP) | VAF 96/444 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60772412, COSV60776901; called by muse, mutect2, varscan2
- EHMT1 | c.854T>C p.V285A | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.98); catalogued as COSV58370510; called by muse, varscan2
- EIF3F | c.524C>T p.T175M | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376154162; called by muse, mutect2, varscan2
- ENAH | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 77/283 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.136); catalogued as rs1228718662, COSV52864991; called by muse, mutect2, varscan2
- EPB41L4B | c.1694A>T p.E565V | Missense Mutation (SNP) | VAF 122/159 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV65801741; called by muse, mutect2, varscan2
- FAM135B | c.3136T>C p.S1046P | Missense Mutation (SNP) | VAF 107/184 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV52704284; called by muse, mutect2, varscan2
- FEM1B | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1444999383, COSV60987719; called by muse, mutect2
- FGF17 | c.277T>G p.F93V | Missense Mutation (SNP) | VAF 89/297 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV63925316; called by muse, mutect2, varscan2
- FHDC1 | c.2674C>T p.R892W | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369934635; called by muse, mutect2, varscan2
- FMO5 | c.1277A>G p.H426R | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.625); catalogued as COSV54204424; called by muse, mutect2, varscan2
- GABPB1 | c.1019A>C p.E340A | Missense Mutation (SNP) | VAF 143/190 reads (75%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV55013530; called by muse, mutect2, varscan2
- GCNT1 | c.68T>C p.V23A | Missense Mutation (SNP) | VAF 63/126 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV65056852; called by muse, mutect2, varscan2
- GNAL | c.663G>A p.W221* (on ENST00000269162 / NM_001142339.3; = p.W298* on NM_182978.4) | Nonsense Mutation (SNP) | VAF 266/692 reads (38%) | catalogued as COSV52323141; called by muse, mutect2, varscan2
- GNL1 | c.1265C>A p.P422H | Missense Mutation (SNP) | VAF 41/212 reads (19%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.663); catalogued as COSV64920665; called by muse, mutect2, varscan2
- GNL2 | c.1064G>T p.R355L | Missense Mutation (SNP) | VAF 50/267 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV66079583; called by muse, mutect2, varscan2
- GPRC5A | c.88G>A p.V30I | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as rs775011273, COSV50007301; called by muse, mutect2, varscan2
- GYS2 | c.1739G>A p.R580H | Missense Mutation (SNP) | VAF 16/276 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762150312, COSV53920433; called by muse, mutect2
- HPCAL1 | c.95A>G p.K32R | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV57144307; called by muse, mutect2, varscan2
- HRNR | c.5674G>T p.G1892C | Missense Mutation (SNP) | VAF 212/3403 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV100914055, COSV64253989; called by muse, mutect2
- INPP5K | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 50/87 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs763835790, COSV57439815; called by muse, mutect2, varscan2
- INSL4 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 32/287 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.368); catalogued as rs144148792, COSV53329893; called by muse, mutect2, varscan2
- KIF14 | c.518C>G p.S173C | Missense Mutation (SNP) | VAF 90/228 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV66259819, COSV66262318; called by muse, mutect2, varscan2
- KRT73 | c.426G>C p.K142N | Missense Mutation (SNP) | VAF 78/210 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV59837847; called by muse, mutect2, varscan2
- MANEA | c.172A>T p.N58Y | Missense Mutation (SNP) | VAF 61/296 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.173); catalogued as COSV62589228; called by muse, mutect2, varscan2
- MAP2K4 | c.569_591del p.K190Rfs*47 | Frame Shift Del (DEL) | VAF 123/198 reads (62%) | catalogued as COSV62254875; called by mutect2, pindel, varscan2
- MBD5 | c.1982A>T p.Q661L | Missense Mutation (SNP) | VAF 50/208 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.157); catalogued as COSV68695738; called by muse, mutect2, varscan2
- MLH1 | c.1501A>G p.I501V | Missense Mutation (SNP) | VAF 18/207 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs748613173, COSV51614137; ClinVar: uncertain significance; called by muse, mutect2
- MME | c.1751A>G p.H584R | Missense Mutation (SNP) | VAF 254/528 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64705951; called by muse, mutect2, varscan2
- MUC17 | c.12302G>A p.R4101Q | Missense Mutation (SNP) | VAF 24/652 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs986544449, COSV100072820, COSV60279719; called by muse, mutect2
- MYBPC2 | c.1022T>G p.V341G | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV63093306; called by muse, mutect2
- NEFM | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 34/169 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55330278; called by muse, mutect2, varscan2
- NINL | c.2040G>T p.E680D | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as COSV53998463; called by muse, mutect2, varscan2
- NIPAL1 | c.355G>T p.V119L | Missense Mutation (SNP) | VAF 122/423 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV55005696; called by muse, mutect2, varscan2
- NPAT | c.296T>C p.M99T | Missense Mutation (SNP) | VAF 91/304 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV53715881; called by muse, mutect2, varscan2
- OAS2 | c.1277A>T p.N426I | Missense Mutation (SNP) | VAF 121/258 reads (47%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.541); catalogued as COSV60801069, COSV60801162; called by muse, mutect2, varscan2
- OR2B3 | c.725G>A p.G242E | Missense Mutation (SNP) | VAF 54/226 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV65850728; called by muse, mutect2, varscan2
- OR2M7 | c.834C>A p.Y278* | Nonsense Mutation (SNP) | VAF 96/303 reads (32%) | catalogued as COSV58737722; called by muse, mutect2, varscan2
- OR51T1 | c.19A>G p.T7A | Missense Mutation (SNP) | VAF 70/281 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.444); catalogued as COSV59023592, COSV59025945; called by muse, mutect2, varscan2
- PAPOLA | c.1259C>G p.S420* | Nonsense Mutation (SNP) | VAF 14/348 reads (4%) | catalogued as COSV53478884; called by muse, mutect2
- PCDH9 | c.3145C>T p.R1049C (on ENST00000377865 / NM_203487.3; = p.R1015C on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs776798396, COSV60527884, COSV60555212; called by muse, mutect2, varscan2
- PDE1C | c.212T>C p.V71A | Missense Mutation (SNP) | VAF 104/388 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV58503104; called by muse, mutect2, varscan2
- PER2 | c.3452A>G p.Y1151C | Missense Mutation (SNP) | VAF 95/288 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54521306; called by muse, mutect2, varscan2
- PLCB4 | c.3337A>G p.S1113G | Missense Mutation (SNP) | VAF 63/270 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.074); catalogued as COSV53792830; called by muse, mutect2, varscan2
- PPP1R12B | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 14/240 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV61113069; called by muse, mutect2
- PSME4 | c.5413del p.T1805Pfs*69 | Frame Shift Del (DEL) | VAF 121/392 reads (31%) | catalogued as COSV101122574; called by mutect2, varscan2
- RASA2 | c.1188del p.F396Lfs*14 | Frame Shift Del (DEL) | VAF 68/257 reads (26%) | catalogued as rs1447555467; called by mutect2, pindel, varscan2
- RBM11 | c.703C>T p.Q235* | Nonsense Mutation (SNP) | VAF 110/390 reads (28%) | catalogued as COSV68747929; called by muse, mutect2, varscan2
- RBM46 | c.717T>A p.Y239* | Nonsense Mutation (SNP) | VAF 24/93 reads (26%) | catalogued as COSV55976961; called by muse, mutect2, varscan2
- RNF112 | c.736G>A p.V246M | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71978751; called by muse, mutect2
- RPRD1B | c.508C>A p.P170T | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV65032283; called by muse, mutect2, varscan2
- SAMD4B | c.164T>A p.I55N | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV58750053; called by muse, mutect2, varscan2
- SEMA4A | c.1237G>A p.V413M | Missense Mutation (SNP) | VAF 52/219 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs764520336, COSV61771873; called by muse, mutect2, varscan2
- SENP1 | c.1227del p.G410Vfs*4 | Frame Shift Del (DEL) | VAF 104/349 reads (30%) | catalogued as rs750651342; called by mutect2, varscan2
- SGCA | c.793G>T p.G265C | Missense Mutation (SNP) | VAF 61/132 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100006636, COSV56248234; called by muse, mutect2, varscan2
- SHPRH | c.495del p.E166Nfs*3 | Frame Shift Del (DEL) | VAF 56/221 reads (25%) | catalogued as rs1469942319; called by mutect2, varscan2
- SLC14A2 | c.1798G>T p.G600C | Missense Mutation (SNP) | VAF 97/335 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54906063; called by muse, mutect2, varscan2
- SLC25A40 | c.940T>G p.C314G | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56690335; called by muse, mutect2, varscan2
- SLC9A9 | c.1082C>G p.T361S | Missense Mutation (SNP) | VAF 21/506 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs1057518347, COSV57217683; ClinVar: uncertain significance; called by muse, mutect2
- SOAT2 | c.389G>A p.G130D | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV56856992; called by muse, mutect2, varscan2
- SPATA22 | c.37A>G p.T13A | Missense Mutation (SNP) | VAF 66/136 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.721); catalogued as COSV52151501; called by muse, mutect2, varscan2
- SYK | c.1775G>T p.G592V | Missense Mutation (SNP) | VAF 105/227 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); catalogued as COSV65325128; called by muse, mutect2, varscan2
- SYT2 | c.178+2T>A p.X60_splice | Splice Site (SNP) | VAF 35/151 reads (23%) | catalogued as COSV66141150; called by muse, mutect2, varscan2
- TFRC | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 16/262 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs772641140, COSV100786409, COSV64053836; called by muse, mutect2
- TIGD4 | c.883G>T p.E295* | Nonsense Mutation (SNP) | VAF 52/190 reads (27%) | catalogued as COSV58548932; called by muse, mutect2, varscan2
- TNFRSF21 | c.796G>C p.V266L | Missense Mutation (SNP) | VAF 149/799 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as COSV57279995; called by muse, mutect2, varscan2
- TRPV3 | c.956G>A p.R319H | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs151284467, COSV56788480; ClinVar: benign; called by muse, mutect2, varscan2
- UPK1B | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 58/207 reads (28%) | SIFT tolerated (0.96); PolyPhen benign (0.001); catalogued as rs776227161, COSV51765991; called by muse, mutect2, varscan2
- USH2A | c.12104C>G p.P4035R | Missense Mutation (SNP) | VAF 98/228 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as CM1410078, COSV56326476; called by muse, mutect2, varscan2
- VPS13B | c.10139C>T p.A3380V | Missense Mutation (SNP) | VAF 46/184 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs199931583, COSV104420642, COSV62132903; called by muse, mutect2, varscan2
- VPS52 | c.1909C>T p.R637W | Missense Mutation (SNP) | VAF 53/276 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs1283456787, COSV69385199; called by muse, mutect2, varscan2
- WASF3 | c.920del p.P307Rfs*28 | Frame Shift Del (DEL) | VAF 6/9 reads (67%) | catalogued as rs756173793; called by mutect2, varscan2
- WBP1L | c.368G>T p.S123I | Missense Mutation (SNP) | VAF 49/90 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV64009287; called by muse, mutect2, varscan2
- XPR1 | c.2009G>A p.R670H | Missense Mutation (SNP) | VAF 116/277 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs142675657; called by muse, mutect2, varscan2
- ZC3HAV1 | c.10C>A p.P4T | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54293188; called by muse, mutect2, varscan2
- ZNF496 | c.1598G>A p.R533Q | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.235); catalogued as COSV54173384; called by muse, mutect2, varscan2
- ZNF532 | c.3119A>G p.Y1040C | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV60171772; called by muse, mutect2, varscan2
- ZNF768 | c.1486C>T p.R496C | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV63319997; called by muse, mutect2, varscan2
- CDH19 | c.1321A>G p.T441A | Missense Mutation (SNP) | VAF 18/336 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0.132); called by muse, mutect2
- KTN1 | c.2978del p.P993Lfs*6 | Frame Shift Del (DEL) | VAF 42/187 reads (22%) | called by mutect2, pindel, varscan2
- MAGEB3 | c.158dup p.S54Vfs*4 | Frame Shift Ins (INS) | VAF 14/39 reads (36%) | called by mutect2, pindel, varscan2
- MRGPRE | c.407_423del p.P136Lfs*154 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | called by mutect2, pindel
- MRGPRE | c.171_198del p.F58Afs*45 | Frame Shift Del (DEL) | VAF 8/56 reads (14%) | called by mutect2, pindel
- MTPAP | c.913del p.I305Yfs*2 | Frame Shift Del (DEL) | VAF 31/179 reads (17%) | called by mutect2, pindel, varscan2
- NFE2L2 | c.159dup p.L54Tfs*2 | Frame Shift Ins (INS) | VAF 116/458 reads (25%) | called by mutect2, pindel, varscan2
- OR13C9 | c.39dup p.L14Sfs*11 | Frame Shift Ins (INS) | VAF 52/146 reads (36%) | called by mutect2, pindel, varscan2
- PHF14 | c.1431_1433del p.L478del | In Frame Del (DEL) | VAF 73/282 reads (26%) | called by mutect2, pindel, varscan2
- SLC22A16 | c.122_123del p.S41Cfs*24 | Frame Shift Del (DEL) | VAF 27/171 reads (16%) | called by mutect2, pindel, varscan2
- XKR3 | c.1121G>A p.C374Y | Missense Mutation (SNP) | VAF 43/82 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- ABCG2 | c.459G>A p.T153= | Silent (SNP) | VAF 174/447 reads (39%) | catalogued as rs1000749135, COSV52942909; called by muse, mutect2, varscan2
- ACCSL | c.744C>T p.A248= | Silent (SNP) | VAF 343/749 reads (46%) | catalogued as COSV66579965; called by muse, mutect2, varscan2
- ADCY6 | c.3387C>A p.T1129= | Silent (SNP) | VAF 26/183 reads (14%) | catalogued as COSV57166182; called by muse, mutect2, varscan2
- ARHGAP1 | c.1218G>A p.A406= | Silent (SNP) | VAF 48/348 reads (14%) | catalogued as rs754507862, COSV56317380; called by muse, mutect2, varscan2
- COL6A5 | c.7015C>T p.L2339= (on ENST00000312481; = p.L2335= on NM_153264.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 132/308 reads (43%) | catalogued as COSV55193438, COSV55214127; called by muse, mutect2, varscan2
- CPS1 | c.4197C>T p.N1399= | Silent (SNP) | VAF 49/124 reads (40%) | catalogued as rs548201746, COSV51801812; called by muse, mutect2, varscan2
- FAM47C | c.945A>G p.V315= | Silent (SNP) | VAF 12/156 reads (8%) | catalogued as rs1569416787, COSV63723561; called by muse, mutect2
- GART | c.1971G>A p.T657= | Silent (SNP) | VAF 35/152 reads (23%) | catalogued as rs142084025; called by muse, mutect2, varscan2
- GLI3 | c.2752C>T p.L918= | Silent (SNP) | VAF 18/37 reads (49%) | catalogued as COSV67885124; called by muse, mutect2, varscan2
- GRM4 | c.132C>A p.R44= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as rs1168826438, COSV65210485; called by muse, mutect2, varscan2
- HERC2 | c.10740C>T p.Y3580= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as COSV55307059; called by muse, mutect2, varscan2
- IQCC | c.552T>A p.R184= | Silent (SNP) | VAF 7/132 reads (5%) | catalogued as COSV52207462; called by muse, mutect2
- MAML2 | c.75G>A p.G25= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV101594183, COSV73262659; called by muse, mutect2
- MAP10 | c.672G>A p.P224= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV69362711; called by muse, mutect2, varscan2
- MYH2 | c.696C>G p.A232= | Silent (SNP) | VAF 97/189 reads (51%) | catalogued as rs972612479, COSV55431398; called by muse, mutect2, varscan2
- NRK | c.2892T>C p.D964= | Silent (SNP) | VAF 137/169 reads (81%) | catalogued as COSV54589647; called by muse, mutect2, varscan2
- PCDHA2 | c.1914C>T p.D638= | Silent (SNP) | VAF 62/85 reads (73%) | catalogued as COSV65364522; called by muse, mutect2, varscan2
- PDE4DIP | c.6360T>C p.G2120= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs1196896374, COSV57674231; called by mutect2, varscan2
- PGM5 | c.1566C>T p.Y522= | Silent (SNP) | VAF 73/156 reads (47%) | catalogued as rs782534536, COSV67166795; called by muse, mutect2, varscan2
- POLE | c.1419C>T p.Y473= | Silent (SNP) | VAF 66/290 reads (23%) | catalogued as rs369961557; ClinVar: likely benign; called by muse, mutect2, varscan2
- SOCS5 | c.693T>C p.H231= | Silent (SNP) | VAF 27/91 reads (30%) | catalogued as COSV60603705; called by muse, mutect2, varscan2
- SZT2 | c.6117C>T p.D2039= (on ENST00000634258 / NM_001365999.1; = p.D1982= on NM_015284.4) | Silent (SNP) | VAF 61/297 reads (21%) | catalogued as rs756197807, COSV65167164; ClinVar: likely benign; called by muse, mutect2, varscan2
- TBC1D4 | c.576T>C p.N192= | Silent (SNP) | VAF 49/113 reads (43%) | catalogued as COSV66487578; called by muse, mutect2, varscan2
- UACA | c.2913G>A p.K971= | Silent (SNP) | VAF 33/325 reads (10%) | catalogued as COSV59853227; called by muse, mutect2, varscan2
- UBR4 | c.14238G>A p.P4746= | Silent (SNP) | VAF 24/37 reads (65%) | catalogued as rs747943634, COSV64382707; called by muse, mutect2, varscan2
- YTHDC1 | c.1800A>G p.G600= (on ENST00000344157 / NM_001031732.4; = p.G582= on NM_133370.4) | Silent (SNP) | VAF 71/213 reads (33%) | catalogued as COSV60008635; called by muse, mutect2, varscan2
- ZNF292 | c.3636T>C p.N1212= | Silent (SNP) | VAF 51/200 reads (26%) | catalogued as COSV60535474; called by muse, mutect2, varscan2
- ALKBH8 | c.-2C>A | 5'UTR (SNP) | VAF 58/189 reads (31%) | catalogued as COSV52833268; called by muse, mutect2, varscan2
- HERC2P3 | n.1771C>T | RNA (SNP) | VAF 50/227 reads (22%) | catalogued as rs146371272; called by muse, mutect2, varscan2
- KSR1 | c.1510+505C>T | Intron (SNP) | VAF 83/146 reads (57%) | catalogued as COSV52028166; called by muse, mutect2, varscan2
- MIR124-2 | n.107G>A | RNA (SNP) | VAF 47/199 reads (24%) | called by muse, mutect2, varscan2
